Somatic mutation profile of tumor specimen 0DUKHJ from CCDI case PBCLHP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 2.1 years (764 days).
Specimen 0DUKHJ: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d78d742-5efd-4420-9ce0-833c077deb60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUKIT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62071408-b0df-4607-aed2-555565bd5aed

The open-access MAF lists 28 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 7, Intron 2, 3'UTR 1, Nonsense Mutation 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL3 | c.4056C>G p.N1352K | Missense Mutation (SNP) | VAF 115/559 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as rs1251520457; called by muse, mutect2, varscan2
- DNAH6 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 14/537 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1558692612, COSV52882900; called by muse, mutect2
- REPS1 | c.1807C>T p.R603C (on ENST00000450536 / NM_001286611.2; = p.R602C on NM_031922.4) | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs767640135; called by muse, mutect2, varscan2
- SIGLEC8 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 26/392 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as rs776742264, COSV58471887; called by muse, mutect2
- SLC27A2 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs757049403, COSV51057903, COSV51059226; called by muse, mutect2, varscan2
- SLIT3 | c.2648G>A p.R883H | Missense Mutation (SNP) | VAF 127/497 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs761012302, COSV60593616; called by muse, mutect2, varscan2
- SPSB4 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 108/336 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as rs747490971, COSV100141615, COSV60145062; called by muse, mutect2, varscan2
- VSIG4 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 93/202 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs777260379, COSV66073951; called by muse, mutect2, varscan2
- AURKAIP1 | c.446A>C p.K149T | Missense Mutation (SNP) | VAF 292/542 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- H2BE1 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 53/353 reads (15%) | called by muse, mutect2, varscan2
- IGF1R | c.802A>G p.T268A | Missense Mutation (SNP) | VAF 3692/3835 reads (96%) | SIFT tolerated (0.18); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- MTOR | c.386C>A p.A129D | Missense Mutation (SNP) | VAF 121/442 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- NID2 | c.3080T>A p.L1027Q | Missense Mutation (SNP) | VAF 86/385 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- NUDT7 | c.605T>C p.I202T | Missense Mutation (SNP) | VAF 23/614 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.372); called by muse, mutect2
- OR1N1 | c.154C>A p.H52N | Missense Mutation (SNP) | VAF 17/225 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.341); called by muse, mutect2
- RASIP1 | c.1417C>G p.P473A | Missense Mutation (SNP) | VAF 63/393 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- CYP4A22 | c.367C>T p.L123= | Silent (SNP) | VAF 96/395 reads (24%) | called by muse, mutect2, varscan2
- INPP4B | c.51T>G p.P17= | Silent (SNP) | VAF 146/158 reads (92%) | called by muse, mutect2, varscan2
- KDM7A | c.1164A>T p.L388= | Silent (SNP) | VAF 64/388 reads (16%) | catalogued as COSV50090330, COSV50090468; called by muse, mutect2, varscan2
- MROH5 | c.522C>T p.N174= | Silent (SNP) | VAF 20/284 reads (7%) | called by muse, mutect2
- PHRF1 | c.3849C>T p.L1283= (on ENST00000264555 / NM_001286581.2; = p.L1282= on NM_020901.4) | Silent (SNP) | VAF 136/316 reads (43%) | catalogued as rs765894190; called by muse, mutect2, varscan2
- RAPGEFL1 | c.513C>T p.A171= | Silent (SNP) | VAF 12/220 reads (5%) | catalogued as COSV52865510; called by muse, mutect2
- TXNDC16 | c.1371T>G p.T457= | Silent (SNP) | VAF 66/260 reads (25%) | catalogued as rs143266054; called by muse, mutect2, varscan2
- ANKRD40CL | chr17:50767011 T>C | 5'Flank (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- CROT | c.240+27A>T | Intron (SNP) | VAF 59/273 reads (22%) | called by muse, mutect2, varscan2
- DOT1L | c.1660-97G>C | Intron (SNP) | VAF 67/376 reads (18%) | called by muse, mutect2, varscan2
- FOXE3 | c.*6C>T | 3'UTR (SNP) | VAF 18/243 reads (7%) | catalogued as rs1415611223; called by muse, mutect2
- ORAI1 | c.-94T>G | 5'UTR (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
